Somatic mutation profile of cancer-model specimen HCM-SANG-0273-C18-85A (3D Organoid; aliquot HCM-SANG-0273-C18-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0273-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G3.
Specimen HCM-SANG-0273-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7611e58c-20a1-40fd-9383-7295b2d28887.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0273-C18-10A (Blood Derived Normal), aliquot HCM-SANG-0273-C18-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99ea0f12-b3e5-4652-935a-4e0a0ec2a413

The open-access MAF lists 2,991 somatic variants for this specimen: 2,190 protein-altering or splice-affecting, 683 silent, 118 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,648, Silent 683, Frame Shift Del 335, Nonsense Mutation 78, Frame Shift Ins 74, Intron 70, Splice Region 21, In Frame Del 15, 3'UTR 15, Splice Site 14, 5'Flank 12, 3'Flank 9.

Variants (750 of 2,991; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGT | c.1290del p.F430Lfs*25 | Frame Shift Del (DEL) | VAF 141/291 reads (48%) | catalogued as rs387906578, CD065661; ClinVar: pathogenic; called by mutect2, varscan2
- APC | c.1742del p.K581Rfs*9 | Frame Shift Del (DEL) | VAF 63/179 reads (35%) | catalogued as rs1060503259, CM1110730, COSV57340306; ClinVar: pathogenic; called by pindel, varscan2
- APC | c.5059C>T p.R1687* | Nonsense Mutation (SNP) | VAF 128/240 reads (53%) | catalogued as rs1554086415, COSV99971947; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CA8 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 229/366 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs387906598, CM118190, COSV58771796; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLCN2 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 122/290 reads (42%) | catalogued as rs863225250, COSV99658572; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYRK1A | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 175/360 reads (49%) | catalogued as rs724159948, CM1510734, COSV100117315; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ETV6 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 144/273 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs724159946, CM150818, COSV56765799, COSV56766683; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GAN | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 89/164 reads (54%) | catalogued as rs119485090, CM020938, COSV101633963; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNH2 | c.453del p.T152Pfs*14 | Frame Shift Del (DEL) | VAF 166/433 reads (38%) | catalogued as rs761863251, CD001499; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 121/242 reads (50%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 97/208 reads (47%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 340/482 reads (71%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3R2 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 131/262 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587776934, CM126686, COSV55846573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RD3 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 192/413 reads (46%) | catalogued as rs786205148, CM130361, COSV65362080; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN4A | c.4343G>A p.R1448H | Missense Mutation (SNP) | VAF 176/386 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121908545, CM080526, CM941271, CM951141; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SLC16A1 | c.41del p.P14Qfs*10 | Frame Shift Del (DEL) | VAF 173/423 reads (41%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- STAT3 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 93/220 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs869312890, CM150604, COSV52886109; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.784_786del p.G262del | In Frame Del (DEL) | VAF 117/252 reads (46%) | hotspot (GDC flag); catalogued as rs1567548347; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- TP53 | c.643A>G p.S215G | Missense Mutation (SNP) | VAF 128/294 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs886039484, CD1511147, COSV52675946, COSV52689203, COSV52876251, COSV53707934; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- VRK1 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 85/182 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs387906830, CM118208, COSV53710053; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ZAP70 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 164/450 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137853201, CM016238, COSV53852423; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 162/333 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780476557; called by muse, varscan2
- AATK | c.3374C>T p.S1125L (on ENST00000326724 / NM_001080395.3; = p.S1022L on NM_004920.2) | Missense Mutation (SNP) | VAF 236/444 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1199723204; called by muse, varscan2
- ABCB8 | c.1822C>T p.R608W (on ENST00000297504 / NM_001282291.2; = p.R591W on NM_007188.5) | Missense Mutation (SNP) | VAF 131/247 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777638983; called by muse, mutect2, varscan2
- ABHD17A | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 148/306 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.255); catalogued as rs536953984; called by muse, mutect2, varscan2
- AC011455.2 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 129/303 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1164866627; called by muse, mutect2, varscan2
- AC132217.2 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 194/415 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as rs1304549931, COSV56097132; called by muse, mutect2, varscan2
- AC139530.2 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 130/274 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.066); catalogued as rs755025904, COSV61367305; called by muse, mutect2, varscan2
- ACACB | c.3163G>A p.A1055T | Missense Mutation (SNP) | VAF 173/424 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.105); catalogued as rs373113364; called by muse, mutect2, varscan2
- ACBD4 | c.649G>A p.G217R (on ENST00000376955 / NM_001378111.1; = p.R220Q on NM_024722.4) | Missense Mutation (SNP) | VAF 196/400 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs756375848; called by muse, mutect2
- ACTBL2 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 217/431 reads (50%) | catalogued as rs775550635; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 222/232 reads (96%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVR2B | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 258/549 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as rs371756878, COSV61702820; called by muse, mutect2, varscan2
- ADA2 | c.426del p.I143Sfs*41 | Frame Shift Del (DEL) | VAF 154/400 reads (39%) | catalogued as COSV52830574; called by mutect2, pindel, varscan2
- ADAM12 | c.970A>G p.M324V | Missense Mutation (SNP) | VAF 120/252 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64107112; called by muse, mutect2, varscan2
- ADAM23 | c.2395G>A p.A799T | Missense Mutation (SNP) | VAF 146/305 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs751280747; called by muse, mutect2, varscan2
- ADAMTS16 | c.3332C>T p.P1111L | Missense Mutation (SNP) | VAF 187/381 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs763057873, COSV56995955, COSV99941372; called by muse, mutect2, varscan2
- ADAMTS6 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 161/331 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.327); catalogued as COSV66862422; called by muse, mutect2, varscan2
- ADAMTS9 | c.3950G>A p.R1317Q | Missense Mutation (SNP) | VAF 186/364 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.155); catalogued as rs746102150; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 235/475 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs144648219; called by muse, mutect2, varscan2
- ADCY1 | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 117/258 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs752410249; called by muse, mutect2, varscan2
- ADCY3 | c.1391T>C p.L464P | Missense Mutation (SNP) | VAF 179/364 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53167430; called by muse, mutect2, varscan2
- ADCY3 | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 142/315 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV53168476; called by muse, mutect2, varscan2
- ADCY9 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 259/494 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53576434; called by muse, mutect2, varscan2
- ADGRA2 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 221/422 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.466); catalogued as rs762613563; called by muse, varscan2
- ADGRF1 | c.1643G>A p.G548D | Missense Mutation (SNP) | VAF 173/377 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51948199; called by muse, mutect2, varscan2
- ADGRL1 | c.2773A>G p.I925V (on ENST00000340736 / NM_001008701.3; = p.I920V on NM_014921.5) | Missense Mutation (SNP) | VAF 108/288 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.08); catalogued as rs140213916; called by muse, mutect2, varscan2
- ADGRL3 | c.875G>A p.R292H (on ENST00000506720 / NM_001322402.2; = p.R224H on NM_015236.6) | Missense Mutation (SNP) | VAF 166/324 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747554116, COSV72269499; called by muse, mutect2, varscan2
- ADGRV1 | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 126/249 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs764427149; called by muse, mutect2, varscan2
- ADGRV1 | c.15271del p.Y5091Tfs*7 | Frame Shift Del (DEL) | VAF 94/192 reads (49%) | catalogued as rs1435790810; called by mutect2, varscan2
- ADORA2B | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 163/360 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs78982650, COSV58483258; called by muse, mutect2, varscan2
- ADORA3 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 158/313 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs549694029; called by muse, mutect2, varscan2
- ADPRHL1 | c.3625G>A p.A1209T | Missense Mutation (SNP) | VAF 344/674 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.454); catalogued as rs1170097653; called by muse, mutect2, varscan2
- ADRA1D | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 324/646 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1356894199; called by muse, mutect2, varscan2
- ADSS1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 166/358 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1245311145; called by muse, mutect2, varscan2
- ADSS1 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 130/264 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.847); catalogued as rs999498738, COSV58276014; called by muse, mutect2, varscan2
- AFF1 | c.2707A>G p.T903A | Missense Mutation (SNP) | VAF 172/342 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs757921988; called by muse, mutect2, varscan2
- AGAP2 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 245/571 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs750302283; called by mutect2, varscan2
- AGO2 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 169/704 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV55046684; called by muse, mutect2, varscan2
- AHNAK2 | c.13755del p.D4586Mfs*36 | Frame Shift Del (DEL) | VAF 163/434 reads (38%) | catalogued as COSV60916374; called by mutect2, pindel, varscan2
- AKR7A2 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 132/288 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs146046785, COSV52515657; called by muse, varscan2
- ALDH3A1 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 99/314 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.374); catalogued as rs769552132; called by muse, mutect2, varscan2
- ALPK3 | c.3136C>T p.R1046C | Missense Mutation (SNP) | VAF 245/512 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs34414438; called by muse, mutect2, varscan2
- AMOT | c.1478T>C p.M493T (on ENST00000371959 / NM_001113490.1; = p.M84T on NM_133265.3) | Missense Mutation (SNP) | VAF 201/201 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59061012; called by muse, mutect2, varscan2
- AMOTL2 | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 216/432 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs745957994; called by muse, varscan2
- ANAPC1 | c.3131C>T p.A1044V | Missense Mutation (SNP) | VAF 132/289 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as rs1342539747; called by muse, mutect2, varscan2
- ANAPC7 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 134/287 reads (47%) | catalogued as rs1198509709, COSV71443740; called by muse, mutect2, varscan2
- ANKRD13B | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 161/330 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs779850469, COSV61471054; called by muse, mutect2, varscan2
- ANKRD26 | c.1110del p.E371Kfs*12 | Frame Shift Del (DEL) | VAF 81/237 reads (34%) | catalogued as rs775948884, COSV65797837; called by mutect2, pindel, varscan2
- ANKRD66 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 147/338 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as rs908132458, COSV71267265, COSV71267295; called by muse, mutect2, varscan2
- ANKS1A | c.181del p.L61Sfs*13 | Frame Shift Del (DEL) | VAF 168/488 reads (34%) | catalogued as rs1201951499; called by pindel, varscan2
- AOX1 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 186/398 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs757671419; called by muse, mutect2, varscan2
- AP002748.5 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 173/350 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV59147994; called by muse, varscan2
- AP3B1 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 122/239 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs964935640, COSV99079483; called by muse, mutect2, varscan2
- APOBEC3D | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 97/237 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.374); catalogued as rs776326105, COSV53328225; called by muse, mutect2, varscan2
- APOD | c.173A>G p.N58S | Missense Mutation (SNP) | VAF 144/285 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1031936520; called by muse, mutect2, varscan2
- APOF | c.705del p.P236Lfs*4 | Frame Shift Del (DEL) | VAF 226/548 reads (41%) | catalogued as COSV58477085; called by mutect2, pindel, varscan2
- APP | c.2239C>T p.R747C | Missense Mutation (SNP) | VAF 136/312 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244541473, COSV60999774; called by muse, mutect2, varscan2
- ARFGAP2 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs150524180; called by muse, mutect2, varscan2
- ARHGAP22 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 224/436 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372857506; called by muse, mutect2, varscan2
- ARHGAP33 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as rs764058770, COSV50129328; called by muse, mutect2, varscan2
- ARHGAP45 | c.3274G>A p.G1092S | Missense Mutation (SNP) | VAF 226/431 reads (52%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs148933347; called by muse, mutect2, varscan2
- ARHGEF10 | c.1515G>T p.S505= (on ENST00000398564; = p.S480= on NM_014629.4) | Splice Region (SNP) | VAF 190/374 reads (51%) | catalogued as COSV50648933; called by muse, mutect2, varscan2
- ARHGEF17 | c.4664C>T p.A1555V | Missense Mutation (SNP) | VAF 197/410 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as rs1032590899, COSV55232909; called by muse, mutect2, varscan2
- ARID1A | c.4541C>T p.T1514M | Missense Mutation (SNP) | VAF 210/403 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs889246106, COSV61377853; called by muse, mutect2, varscan2
- ARMH1 | c.382C>A p.L128I | Missense Mutation (SNP) | VAF 136/317 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100679659; called by muse, mutect2, varscan2
- ARSA | c.1336G>T p.G446C | Missense Mutation (SNP) | VAF 231/442 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.241); catalogued as rs1347351089, COSV99332357; called by muse, mutect2, varscan2
- ARVCF | c.1615C>T p.R539* | Nonsense Mutation (SNP) | VAF 252/514 reads (49%) | catalogued as rs779111860; called by muse, mutect2, varscan2
- ASB12 | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 243/243 reads (100%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV62856425; called by muse, mutect2, varscan2
- ASB14 | c.371del p.L124Wfs*8 (on ENST00000389601; = p.L123Wfs*8 on NM_001142733.3) | Frame Shift Del (DEL) | VAF 162/340 reads (48%) | catalogued as rs770471078; called by mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 108/245 reads (44%) | catalogued as rs747570359; called by mutect2, varscan2
- ASPA | c.584T>C p.M195T | Missense Mutation (SNP) | VAF 99/219 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as CM990195; called by muse, mutect2, varscan2
- ASRGL1 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 135/272 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.277); catalogued as rs145306822; called by muse, mutect2, varscan2
- ATF4 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 142/287 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.053); catalogued as rs994266051; called by muse, mutect2, varscan2
- ATG2B | c.3398G>A p.R1133Q | Missense Mutation (SNP) | VAF 108/279 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs373581781; called by muse, mutect2, varscan2
- ATIC | c.1762C>T p.R588W | Missense Mutation (SNP) | VAF 120/266 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs1251129229; called by muse, mutect2, varscan2
- ATL3 | c.1282T>G p.F428V | Missense Mutation (SNP) | VAF 134/370 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV60295276; called by muse, mutect2, varscan2
- ATP1A1 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as rs1429384765, COSV55189682, COSV55192203; called by muse, mutect2, varscan2
- ATP1A1 | c.3035G>A p.R1012H | Missense Mutation (SNP) | VAF 99/184 reads (54%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs746521823, COSV55191200; called by muse, mutect2, varscan2
- ATP1A4 | c.69del p.I26Sfs*6 | Frame Shift Del (DEL) | VAF 145/345 reads (42%) | catalogued as rs1467294583; called by mutect2, pindel, varscan2
- ATP2C1 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 129/255 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs756074470, COSV60758511; called by muse, mutect2, varscan2
- ATP6V0C | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 316/673 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1455923972; called by muse, mutect2, varscan2
- ATP6V1FNB | c.359A>G p.D120G | Missense Mutation (SNP) | VAF 187/380 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.155); catalogued as rs1439870287; called by muse, mutect2, varscan2
- ATP6V1H | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 116/318 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs371234673; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 138/333 reads (41%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- B3GLCT | c.1135G>A p.G379S | Missense Mutation (SNP) | VAF 128/262 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375168040, COSV58456500; called by muse, mutect2, varscan2
- B3GNT4 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 253/567 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs762842306, COSV57336727, COSV99927964; called by muse, mutect2, varscan2
- B4GALNT1 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 169/382 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1392167599; called by muse, mutect2, varscan2
- BAHCC1 | c.4496G>A p.R1499H | Missense Mutation (SNP) | VAF 250/489 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.633); catalogued as rs782024906; called by muse, mutect2, varscan2
- BAIAP3 | c.3029G>A p.R1010Q | Missense Mutation (SNP) | VAF 172/479 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs142821453; called by muse, mutect2, varscan2
- BBX | c.2675C>T p.A892V (on ENST00000325805 / NM_001142568.3; = p.A862V on NM_020235.7) | Missense Mutation (SNP) | VAF 149/276 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV57881199; called by muse, mutect2, varscan2
- BCL7C | c.358del p.Q120Sfs*33 | Frame Shift Del (DEL) | VAF 224/547 reads (41%) | catalogued as rs758526156; called by mutect2, pindel, varscan2
- BCL9 | c.2113C>T p.R705W | Missense Mutation (SNP) | VAF 123/344 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs782485553; called by muse, mutect2, varscan2
- BDKRB1 | c.497del p.G166Afs*3 | Frame Shift Del (DEL) | VAF 216/435 reads (50%) | catalogued as rs760605422; called by mutect2, varscan2
- BEAN1 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 151/299 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1012717845; called by muse, mutect2, varscan2
- BEND3 | c.2073dup p.E692Rfs*21 | Frame Shift Ins (INS) | VAF 203/606 reads (33%) | catalogued as rs782172473; called by pindel, varscan2
- BEND5 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 130/296 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1190968609; called by muse, mutect2, varscan2
- BHLHA15 | c.63del p.E23Rfs*69 | Frame Shift Del (DEL) | VAF 293/738 reads (40%) | catalogued as COSV51995477; called by mutect2, pindel, varscan2
- BIN3 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 109/281 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as rs1364873729, COSV52386409; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 166/335 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as rs754132810, COSV99959060; called by muse, mutect2, varscan2
- BOP1 | c.106del p.L36Sfs*154 | Frame Shift Del (DEL) | VAF 271/532 reads (51%) | catalogued as rs782133829; called by mutect2, pindel, varscan2
- BRCA2 | c.2321C>T p.T774I | Missense Mutation (SNP) | VAF 118/229 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.185); catalogued as rs1239876081; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRMS1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 180/344 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200013073; called by muse, mutect2, varscan2
- BSN | c.2530C>T p.R844* | Nonsense Mutation (SNP) | VAF 207/408 reads (51%) | catalogued as COSV56523309; called by muse, mutect2, varscan2
- BTBD8 | c.2491G>A p.A831T (on ENST00000636805 / NM_001376131.1; = p.A318T on NM_015237.4) | Missense Mutation (SNP) | VAF 127/271 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); catalogued as rs748097494; called by muse, mutect2, varscan2
- C11orf21 | c.94G>A p.V32I (on ENST00000381153 / NM_001329958.2; = p.V78I on NM_001142946.3) | Missense Mutation (SNP) | VAF 159/337 reads (47%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as rs905355276; called by muse, mutect2, varscan2
- C12orf42 | c.994T>G p.S332A | Missense Mutation (SNP) | VAF 164/319 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); catalogued as COSV100172253; called by muse, mutect2, varscan2
- C14orf39 | c.1762del p.*588Efs*16 | Frame Shift Del (DEL) | VAF 72/131 reads (55%) | catalogued as rs780875081; called by mutect2, varscan2
- C1QTNF9 | c.899A>T p.E300V | Missense Mutation (SNP) | VAF 171/393 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59657904; called by muse, mutect2, varscan2
- C1orf226 | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 217/446 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1451543453, COSV100908107; called by muse, mutect2, varscan2
- C20orf194 | c.2278G>A p.A760T | Missense Mutation (SNP) | VAF 121/244 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.371); catalogued as rs1352584156; called by muse, mutect2, varscan2
- C20orf194 | c.597dup p.T200Yfs*5 | Frame Shift Ins (INS) | VAF 91/213 reads (43%) | catalogued as rs1221445330; called by mutect2, pindel, varscan2
- C21orf58 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs138995738; called by muse, mutect2, varscan2
- C22orf31 | c.433-1_436del p.X145_splice | Splice Site (DEL) | VAF 85/194 reads (44%) | catalogued as rs752604444; called by mutect2, pindel, varscan2
- C3orf56 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 134/280 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as rs867928890; called by muse, mutect2, varscan2
- C4orf50 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 327/697 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs1290210866; called by muse, mutect2, varscan2
- C5orf38 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 266/609 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.268); catalogued as rs1231627026; called by muse, mutect2, varscan2
- CALN1 | c.569G>A p.R190Q (on ENST00000329008 / NM_001017440.3; = p.R232Q on NM_031468.4) | Missense Mutation (SNP) | VAF 131/266 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767122514, COSV61147636; called by muse, mutect2, varscan2
- CAMK2A | c.1318G>A p.A440T (on ENST00000348628 / NM_171825.2; = p.A451T on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 213/432 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.228); catalogued as rs374924411; called by muse, mutect2, varscan2
- CAMP | c.179G>A p.R60H (on ENST00000296435; = p.R57H on NM_004345.5) | Missense Mutation (SNP) | VAF 131/305 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs201772370; called by muse, mutect2, varscan2
- CAMSAP1 | c.3952G>A p.E1318K | Missense Mutation (SNP) | VAF 161/379 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100409648; called by muse, mutect2, varscan2
- CAMSAP1 | c.2845G>A p.D949N | Missense Mutation (SNP) | VAF 226/439 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV56722023; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 98/305 reads (32%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMTA2 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 189/391 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs778036102; called by muse, mutect2, varscan2
- CARD11 | c.2734C>T p.R912W | Missense Mutation (SNP) | VAF 217/411 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs772829458, COSV62756776; called by muse, mutect2, varscan2
- CARD11 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 156/339 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.861); catalogued as rs1012368675; ClinVar: uncertain significance; called by muse, varscan2
- CARM1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 160/328 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV100499109; called by muse, mutect2, varscan2
- CASR | c.373C>A p.L125I | Missense Mutation (SNP) | VAF 176/351 reads (50%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.824); catalogued as CM0910774; called by muse, mutect2, varscan2
- CBFA2T2 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 175/352 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs1568865269, COSV60799841; called by muse, mutect2, varscan2
- CCDC120 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 192/194 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782816201, COSV64515054; called by muse, mutect2, varscan2
- CCDC168 | c.20186del p.N6729Tfs*19 | Frame Shift Del (DEL) | VAF 128/315 reads (41%) | catalogued as rs745497329; called by mutect2, pindel, varscan2
- CCDC168 | c.9337G>A p.E3113K | Missense Mutation (SNP) | VAF 104/298 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as rs761797818, COSV59422520; called by muse, varscan2
- CCDC177 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 285/562 reads (51%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.997); catalogued as rs1445697268, COSV73457547; called by muse, mutect2, varscan2
- CCDC39 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 103/214 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368439919; called by muse, mutect2, varscan2
- CCDC78 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 206/428 reads (48%) | catalogued as rs776512977; called by muse, mutect2, varscan2
- CCDC88C | c.2184G>T p.R728S | Missense Mutation (SNP) | VAF 230/444 reads (52%) | SIFT tolerated (0.7); PolyPhen benign (0.045); catalogued as COSV66234179; called by muse, mutect2, varscan2
- CCER2 | c.424_426del p.E142del | In Frame Del (DEL) | VAF 242/560 reads (43%) | catalogued as rs1250291575; called by pindel, varscan2
- CCND1 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 169/361 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1373641771, COSV57121549; called by muse, mutect2, varscan2
- CCNL1 | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 164/330 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs970719440, COSV99904279; called by muse, mutect2, varscan2
- CCT6A | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 254/506 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as rs1326892702; called by muse, mutect2, varscan2
- CD14 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 216/457 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as COSV100117681; called by muse, mutect2, varscan2
- CD47 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 86/219 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as rs761086667; called by muse, mutect2, varscan2
- CDC7 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 140/279 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV99319493; called by muse, varscan2
- CDCA7L | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 245/478 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778002499, COSV60938162; called by muse, mutect2, varscan2
- CDH11 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 228/452 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1009453346; called by muse, mutect2
- CDH12 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 161/341 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1171594653, COSV101200838, COSV66444733; called by muse, mutect2, varscan2
- CDH15 | c.1537del p.H513Tfs*9 | Frame Shift Del (DEL) | VAF 260/640 reads (41%) | catalogued as rs763850576, COSV57025343; called by mutect2, pindel, varscan2
- CECR2 | c.4006G>A p.E1336K (on ENST00000342247 / NM_001290047.2; = p.E1152K on NM_001290046.1) | Missense Mutation (SNP) | VAF 170/363 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs1375676607, COSV52844056; called by muse, mutect2, varscan2
- CELF6 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 194/373 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.901); catalogued as rs763073658, COSV99763590; called by muse, mutect2, varscan2
- CELSR1 | c.5062A>G p.M1688V | Missense Mutation (SNP) | VAF 105/201 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as rs376381659; called by muse, mutect2, varscan2
- CELSR1 | c.3493G>A p.D1165N | Missense Mutation (SNP) | VAF 266/543 reads (49%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.707); catalogued as rs142075439; called by muse, varscan2
- CELSR3 | c.5219G>A p.R1740H | Missense Mutation (SNP) | VAF 193/408 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.86); catalogued as rs369198712; called by muse, mutect2, varscan2
- CENPBD1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 97/257 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as rs761413813, COSV51921244; called by muse, mutect2, varscan2
- CEP112 | c.1073del p.K358Sfs*6 | Frame Shift Del (DEL) | VAF 73/138 reads (53%) | catalogued as rs769310263; called by mutect2, varscan2
- CEP170B | c.802G>A p.A268T (on ENST00000453495; = p.A197T on NM_015005.3) | Missense Mutation (SNP) | VAF 259/518 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs370255446, COSV69024168; called by muse, mutect2, varscan2
- CEP290 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 114/233 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs774824252, COSV100468397; called by muse, mutect2, varscan2
- CEP295 | c.1657del p.T553Lfs*15 | Frame Shift Del (DEL) | VAF 75/193 reads (39%) | catalogued as rs749718914; called by mutect2, varscan2
- CES5A | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 166/372 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1277880331, COSV51867486; called by muse, mutect2, varscan2
- CFAP251 | c.3187A>G p.K1063E | Missense Mutation (SNP) | VAF 112/235 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1191796934; called by muse, mutect2, varscan2
- CHD7 | c.3949C>T p.R1317C | Missense Mutation (SNP) | VAF 333/470 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs373301291; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHMP7 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 138/261 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); catalogued as rs377356281; called by muse, mutect2, varscan2
- CHPF | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 214/436 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as rs774014211, COSV60534566; called by muse, mutect2, varscan2
- CHRM5 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 170/353 reads (48%) | catalogued as rs1482092786; called by muse, mutect2, varscan2
- CHRNA1 | c.1259C>T p.A420V (on ENST00000261007 / NM_001039523.3; = p.A395V on NM_000079.4) | Missense Mutation (SNP) | VAF 169/370 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs768878508; called by muse, mutect2, varscan2
- CHRNE | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 243/779 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.759); catalogued as rs577641512; called by muse, mutect2, varscan2
- CHST15 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 184/358 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1338359559; called by muse, mutect2, varscan2
- CHST5 | c.377T>C p.M126T | Missense Mutation (SNP) | VAF 193/395 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs200154424; called by muse, mutect2, varscan2
- CIBAR1 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 147/580 reads (25%) | catalogued as rs764514673, COSV63897064; called by muse, mutect2, varscan2
- CILK1 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 161/322 reads (50%) | catalogued as rs551694392; called by muse, mutect2, varscan2
- CLCA4 | c.426dup p.Q143Tfs*3 | Frame Shift Ins (INS) | VAF 86/235 reads (37%) | catalogued as rs1194960391; called by mutect2, varscan2
- CLDN8 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 168/381 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778164419, COSV54525355; called by muse, mutect2, varscan2
- CLEC14A | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 202/400 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs772465937; called by muse, varscan2
- CLEC16A | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 108/209 reads (52%) | catalogued as rs200316563; called by muse, mutect2, varscan2
- CLEC4F | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 174/368 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs149379407; called by muse, mutect2, varscan2
- CLU | c.187dup p.T63Nfs*25 | Frame Shift Ins (INS) | VAF 223/559 reads (40%) | catalogued as rs747368775; called by mutect2, pindel, varscan2
- CLUH | c.436G>A p.D146N (on ENST00000435359; = p.D184N on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 192/425 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs781728255; called by muse, mutect2, varscan2
- CMTM1 | c.180del p.F60Lfs*3 (on ENST00000457188 / NM_181269.3; = p.F177Lfs*3 on NM_052999.4) | Frame Shift Del (DEL) | VAF 140/290 reads (48%) | catalogued as rs773521289; called by mutect2, varscan2
- CNNM3 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 196/434 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs200102903; called by muse, mutect2, varscan2
- CNOT1 | c.4180C>T p.R1394C | Missense Mutation (SNP) | VAF 146/322 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55319614; called by muse, mutect2, varscan2
- CNTNAP1 | c.2500C>T p.R834C | Missense Mutation (SNP) | VAF 122/280 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs756105722, COSV99226936; called by muse, varscan2
- CNTRL | c.5399A>G p.E1800G | Missense Mutation (SNP) | VAF 94/181 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs764744947; called by muse, mutect2, varscan2
- COL12A1 | c.5771G>A p.R1924H | Missense Mutation (SNP) | VAF 138/278 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs751986784, COSV100486301, COSV59395186; called by muse, mutect2, varscan2
- COL18A1 | c.1586C>T p.S529L (on ENST00000359759 / NM_130444.3; = p.S294L on NM_030582.4) | Missense Mutation (SNP) | VAF 277/599 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs373861758; called by muse, mutect2, varscan2
- COL26A1 | c.1083C>T p.G361= (on ENST00000313669 / NM_001278563.3; = p.G359= on NM_133457.4) | Splice Region (SNP) | VAF 118/242 reads (49%) | catalogued as rs751175575; called by muse, mutect2, varscan2
- COL3A1 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 119/227 reads (52%) | catalogued as COSV58588180; called by muse, mutect2, varscan2
- COL4A4 | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as rs374740993; called by muse, mutect2, varscan2
- COL4A4 | c.330T>C p.G110= | Splice Region (SNP) | VAF 66/151 reads (44%) | catalogued as COSV61632873; called by muse, mutect2, varscan2
- COL5A3 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 149/350 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as rs775339681; called by muse, mutect2, varscan2
- COLGALT2 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 97/203 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV62300568; called by muse, mutect2, varscan2
- CPAMD8 | c.5255C>T p.A1752V (on ENST00000651564; = p.A1705V on NM_015692.5) | Missense Mutation (SNP) | VAF 276/559 reads (49%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.02); catalogued as rs1200974057; called by muse, mutect2, varscan2
- CPLANE2 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 104/227 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.202); catalogued as rs941769347; called by muse, mutect2, varscan2
- CPNE1 | c.995+1G>A p.X332_splice (on ENST00000352393; = p.X337_splice on NM_003915.5) | Splice Site (SNP) | VAF 139/283 reads (49%) | catalogued as rs964982391; called by muse, mutect2, varscan2
- CPSF1 | c.4030G>A p.G1344S | Missense Mutation (SNP) | VAF 26/852 reads (3%) | SIFT tolerated (0.68); PolyPhen benign (0.131); catalogued as rs782535642; called by muse, mutect2
- CPXM2 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 224/493 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs934264986; called by muse, varscan2
- CRACR2A | c.1784C>T p.A595V | Missense Mutation (SNP) | VAF 168/324 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs764222855; called by muse, varscan2
- CRB1 | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 86/220 reads (39%) | catalogued as rs1367253589; called by muse, mutect2, varscan2
- CRB1 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 154/354 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.087); catalogued as rs1447630642, COSV66331988; called by muse, mutect2, varscan2
- CREBBP | c.6137C>T p.A2046V | Missense Mutation (SNP) | VAF 216/476 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.051); catalogued as rs753688167, COSV52118312; called by muse, mutect2, varscan2
- CRTC1 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 233/472 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.79); catalogued as rs1367541840, COSV58719618; called by muse, mutect2, varscan2
- CRYBG3 | c.4911A>G p.I1637M | Missense Mutation (SNP) | VAF 133/259 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.012); catalogued as rs1234167351, COSV51712398; called by muse, mutect2, varscan2
- CSH1 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 233/425 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100298184; called by muse, mutect2, varscan2
- CSPG4 | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 246/464 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1163290228, COSV100414007; called by muse, mutect2, varscan2
- CSPP1 | c.1177C>T p.P393S (on ENST00000676605; = p.P352S on NM_024790.6) | Missense Mutation (SNP) | VAF 108/396 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs777179827; called by muse, mutect2, varscan2
- CST4 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 124/254 reads (49%) | catalogued as rs767756120; called by mutect2, varscan2
- CST5 | c.210G>T p.Q70H | Missense Mutation (SNP) | VAF 105/236 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs1416406971; called by muse, mutect2, varscan2
- CTAGE1 | c.2224G>A p.A742T | Missense Mutation (SNP) | VAF 97/243 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1221082236; called by muse, mutect2, varscan2
- CTDP1 | c.2506C>T p.R836* | Nonsense Mutation (SNP) | VAF 172/358 reads (48%) | catalogued as rs1379866383, COSV50010727; called by muse, mutect2, varscan2
- CTNND2 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 166/302 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs955557681; called by muse, varscan2
- CTTNBP2 | c.2119del p.L707Wfs*54 | Frame Shift Del (DEL) | VAF 174/452 reads (38%) | catalogued as COSV50390826; called by mutect2, pindel, varscan2
- CYFIP1 | c.1871G>A p.R624Q | Missense Mutation (SNP) | VAF 198/454 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772456133; called by muse, varscan2
- CYLC2 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 165/356 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs199562230; called by muse, varscan2
- CYP26A1 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 189/394 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV56420219; called by muse, mutect2, varscan2
- CYP26C1 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 297/544 reads (55%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1302494800; called by muse, mutect2, varscan2
- CYP2A13 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 178/355 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV57838577; called by muse, mutect2, varscan2
- CYP2A13 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 169/411 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.538); catalogued as rs377347872; called by muse, mutect2, varscan2
- CYP46A1 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 150/299 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1290457146, COSV55893308; called by muse, mutect2, varscan2
- CYSLTR1 | c.671del p.N224Ifs*9 | Frame Shift Del (DEL) | VAF 164/174 reads (94%) | catalogued as rs766746913; called by mutect2, varscan2
- DACH2 | c.1573del p.T525Pfs*33 | Frame Shift Del (DEL) | VAF 192/263 reads (73%) | catalogued as COSV100912973, COSV64169192; called by mutect2, pindel, varscan2
- DAG1 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 218/446 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.572); catalogued as rs1256677839; called by muse, varscan2
- DBN1 | c.1490C>T p.T497M | Missense Mutation (SNP) | VAF 233/474 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs779281470; called by muse, mutect2, varscan2
- DCHS2 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 205/413 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.699); catalogued as COSV59726622; called by muse, mutect2, varscan2
- DCP1A | c.999del p.S334Afs*8 | Frame Shift Del (DEL) | VAF 164/437 reads (38%) | catalogued as COSV99588276; called by mutect2, pindel, varscan2
- DCTN3 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs550305018; called by muse, mutect2, varscan2
- DCTN4 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 150/305 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs772637602; called by muse, mutect2, varscan2
- DDRGK1 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 150/324 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs779149576; called by muse, mutect2, varscan2
- DENND11 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 320/556 reads (58%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs1373226001; called by muse, mutect2, varscan2
- DENND2A | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 116/239 reads (49%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs375197864; called by muse, mutect2, varscan2
- DENND5A | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 158/303 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV60238481; called by muse, varscan2
- DGKQ | c.2693C>T p.P898L | Missense Mutation (SNP) | VAF 257/494 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs774849818; called by muse, varscan2
- DHCR7 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 143/319 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs1219768413; called by muse, mutect2, varscan2
- DHDH | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 177/406 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs368374944; called by muse, mutect2
- DHX40 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 126/277 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1179083080, COSV99233220; called by muse, mutect2, varscan2
- DIAPH3 | c.2125del p.I709Lfs*7 (on ENST00000400324 / NM_001042517.2; = p.I446Lfs*7 on NM_030932.3) | Frame Shift Del (DEL) | VAF 43/129 reads (33%) | catalogued as rs777749882, COSV99934632; called by mutect2, pindel, varscan2
- DLAT | c.723del p.V242Wfs*5 | Frame Shift Del (DEL) | VAF 93/219 reads (42%) | catalogued as rs782029228, COSV54771743; called by mutect2, varscan2
- DLGAP1 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 280/559 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs755314290; called by muse, mutect2, varscan2
- DLGAP4 | c.2074G>T p.G692W (on ENST00000339266 / NM_001365621.1; = p.G153W on NM_183006.4) | Missense Mutation (SNP) | VAF 141/289 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59414806; called by muse, mutect2, varscan2
- DNAAF5 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 31/573 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.632); catalogued as rs1159798626, COSV52414270; called by muse, mutect2
- DNAH1 | c.1769T>C p.V590A | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as rs1486812384; called by muse, mutect2
- DNAH14 | c.6887C>T p.T2296I (on ENST00000445597; = p.T2949I on NM_001367479.1) | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1444166287; called by muse, mutect2, varscan2
- DNAH17 | c.456G>C p.M152I | Missense Mutation (SNP) | VAF 208/420 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.024); catalogued as COSV101103301; called by muse, mutect2, varscan2
- DNAH2 | c.5345C>T p.T1782M | Missense Mutation (SNP) | VAF 167/332 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145112814; called by muse, mutect2, varscan2
- DNAH3 | c.4195T>C p.S1399P | Missense Mutation (SNP) | VAF 136/295 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs768478465; called by mutect2, varscan2
- DNAH5 | c.11377G>A p.E3793K | Missense Mutation (SNP) | VAF 111/226 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.168); catalogued as rs751996726, COSV54212253; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.9947del p.P3316Lfs*22 | Frame Shift Del (DEL) | VAF 138/370 reads (37%) | catalogued as rs1206989225; called by mutect2, pindel, varscan2
- DNAH6 | c.8539G>C p.E2847Q | Missense Mutation (SNP) | VAF 120/232 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV52854392; called by muse, mutect2, varscan2
- DNAH7 | c.4558C>T p.P1520S | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs762635842; called by muse, varscan2
- DNAH9 | c.8947G>A p.E2983K | Missense Mutation (SNP) | VAF 162/323 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as rs202196562, COSV52366440; called by muse, mutect2, varscan2
- DNMBP | c.1771G>T p.G591C | Missense Mutation (SNP) | VAF 135/338 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60627389; called by muse, mutect2, varscan2
- DOC2B | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 178/346 reads (51%) | SIFT tolerated (1); PolyPhen possibly damaging (0.49); catalogued as rs1431136829; called by muse, mutect2, varscan2
- DOCK4 | c.2914C>T p.R972C | Missense Mutation (SNP) | VAF 90/206 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1187348274, COSV70242181; called by muse, mutect2, varscan2
- DOCK5 | c.4713dup p.T1572Yfs*10 | Frame Shift Ins (INS) | VAF 104/202 reads (51%) | catalogued as rs745668075; called by mutect2, varscan2
- DOT1L | c.3907del p.A1303Lfs*24 | Frame Shift Del (DEL) | VAF 258/617 reads (42%) | catalogued as COSV67113624; called by mutect2, pindel, varscan2
- DPF3 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 139/309 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs781541440, COSV100818442; called by muse, mutect2, varscan2
- DPPA5 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 147/340 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV64875412; called by muse, mutect2, varscan2
- DPYSL3 | c.1545del p.A516Qfs*15 | Frame Shift Del (DEL) | VAF 156/396 reads (39%) | catalogued as COSV58330771; called by mutect2, pindel, varscan2
- DPYSL5 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as rs753410511, COSV56511910, COSV56512276; called by muse, mutect2, varscan2
- DSCAM | c.3659G>A p.R1220Q | Missense Mutation (SNP) | VAF 135/283 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs755579756, COSV68020290; called by muse, mutect2, varscan2
- DSG1 | c.928A>G p.I310V | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs1183135219; called by muse, mutect2, varscan2
- DST | c.2123C>T p.A708V (on ENST00000361203 / NM_001374722.1; = p.A382V on NM_001723.6) | Missense Mutation (SNP) | VAF 170/346 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs778615450, COSV54995697; called by muse, varscan2
- DTHD1 | c.1829G>A p.C610Y (on ENST00000456874; = p.C445Y on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/250 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs1361535637; called by muse, mutect2, varscan2
- DTX4 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 224/442 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs764119701, COSV57088058; called by muse, varscan2
- DUOX2 | c.2110C>A p.R704S | Missense Mutation (SNP) | VAF 124/259 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV101199855; called by muse, mutect2, varscan2
- DUSP7 | c.40A>G p.M14V | Missense Mutation (SNP) | VAF 255/521 reads (49%) | PolyPhen benign (0.001); catalogued as rs1411546728; called by muse, mutect2, varscan2
- E2F3 | c.74T>C p.V25A | Missense Mutation (SNP) | VAF 282/594 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60896100; called by mutect2, varscan2
- E2F7 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 167/369 reads (45%) | catalogued as rs780614837, COSV59739397; called by muse, mutect2, varscan2
- EBF3 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 119/259 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs775229422, COSV62473143; called by muse, mutect2, varscan2
- EDN1 | c.461A>G p.K154R | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV65080527; called by muse, mutect2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 118/278 reads (42%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- EEF1AKMT4-ECE2 | c.2182G>C p.D728H | Missense Mutation (SNP) | VAF 134/302 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62568075; called by muse, mutect2, varscan2
- EHMT1 | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 110/229 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.217); catalogued as rs748381657; called by muse, mutect2, varscan2
- EIF4E | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV55189360, COSV99028484; called by muse, varscan2
- ELAPOR1 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.517); catalogued as rs138845394; called by muse, mutect2, varscan2
- ELOA2 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 176/499 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767426854, COSV55294620; called by muse, mutect2, varscan2
- ELOA3C | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 124/862 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1352166187; called by mutect2, varscan2
- EN2 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 151/329 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763911920, COSV52083595; called by muse, mutect2, varscan2
- ENO4 | c.623A>G p.K208R (on ENST00000622726; = p.K207R on NM_001242699.2) | Missense Mutation (SNP) | VAF 140/290 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV58004922; called by muse, varscan2
- EP400 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 99/242 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1284097784, COSV57787756; called by muse, mutect2, varscan2
- EPHA6 | c.1289G>T p.R430M | Missense Mutation (SNP) | VAF 118/251 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101062032; called by muse, mutect2, varscan2
- EPN1 | c.1112C>T p.P371L (on ENST00000270460 / NM_001321263.1; = p.P346L on NM_013333.3) | Missense Mutation (SNP) | VAF 233/515 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs376939806; called by muse, mutect2, varscan2
- ERC2 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 145/318 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs182610509; called by muse, mutect2, varscan2
- ERICH3 | c.2485dup p.R829Kfs*25 | Frame Shift Ins (INS) | VAF 199/513 reads (39%) | catalogued as rs35151101; called by mutect2, pindel, varscan2
- ETAA1 | c.500G>A p.S167N | Missense Mutation (SNP) | VAF 99/206 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs760157523; called by muse, mutect2, varscan2
- EVC | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 104/222 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs932851648; called by muse, mutect2, varscan2
- EVX2 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 179/296 reads (60%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.045); catalogued as rs1287309577; called by muse, mutect2, varscan2
- EYS | c.341G>A p.C114Y | Missense Mutation (SNP) | VAF 152/285 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); catalogued as rs533909681, COSV100675702, COSV100676978; called by muse, mutect2, varscan2
- F11R | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 110/232 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs745416395; called by muse, varscan2
- F2 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 218/474 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1423659542, COSV61315682; called by muse, mutect2, varscan2
- F5 | c.2422T>C p.S808P | Missense Mutation (SNP) | VAF 130/300 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs778547706; called by muse, mutect2, varscan2
- FAM160A2 | c.2336G>A p.R779H (on ENST00000449352 / NM_001098794.2; = p.R793H on NM_032127.4) | Missense Mutation (SNP) | VAF 225/402 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1382831224, COSV99791644; called by muse, mutect2, varscan2
- FAM193A | c.2527G>A p.V843I | Missense Mutation (SNP) | VAF 123/312 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.8); catalogued as rs182204199; called by muse, mutect2, varscan2
- FAM20A | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 103/222 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs374500334; called by muse, varscan2
- FAM47A | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 234/234 reads (100%) | SIFT tolerated (1); PolyPhen possibly damaging (0.695); catalogued as COSV60496118; called by muse, mutect2, varscan2
- FAM47B | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 271/271 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs770322379, COSV100264611, COSV61452636; called by muse, mutect2, varscan2
- FAM71F1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 132/273 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.063); catalogued as rs145647614; called by muse, varscan2
- FAM78B | c.692del p.P231Lfs*4 | Frame Shift Del (DEL) | VAF 196/487 reads (40%) | catalogued as rs763715884; called by mutect2, pindel, varscan2
- FAM83C | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 283/605 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as rs538477225; called by muse, mutect2, varscan2
- FARP1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 116/273 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs200784439, COSV60335166; called by muse, mutect2, varscan2
- FARP1 | c.689A>G p.H230R | Missense Mutation (SNP) | VAF 141/325 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs199776431; called by muse, mutect2, varscan2
- FARS2 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 127/279 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs745400923, COSV51165800; called by muse, varscan2
- FARSB | c.501G>T p.L167F | Missense Mutation (SNP) | VAF 138/302 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs758903749; called by muse, mutect2, varscan2
- FAT4 | c.12597T>G p.C4199W | Missense Mutation (SNP) | VAF 88/194 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58674832; called by muse, mutect2, varscan2
- FBN1 | c.6916C>T p.R2306C | Missense Mutation (SNP) | VAF 130/271 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1318405523, CM158983, COSV100354870; ClinVar: uncertain significance; called by muse, varscan2
- FBN2 | c.4862G>A p.C1621Y | Missense Mutation (SNP) | VAF 128/251 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52496462, COSV52547611; called by muse, mutect2, varscan2
- FBXL14 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 222/495 reads (45%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.992); catalogued as rs1332976903; called by muse, mutect2, varscan2
- FBXL20 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 88/249 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs1307073259; called by muse, mutect2
- FBXL4 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 122/282 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1331215506; called by muse, mutect2, varscan2
- FBXL7 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 249/518 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as rs746642404, COSV100309458; called by muse, mutect2, varscan2
- FBXL7 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 242/479 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1026833800, COSV61650185; called by muse, mutect2, varscan2
- FBXW10 | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 74/354 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs370583951, COSV100111759; called by muse, mutect2, varscan2
- FCAMR | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 173/332 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.476); catalogued as rs758887790; called by muse, mutect2, varscan2
- FCAMR | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 152/315 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs535083117; called by muse, mutect2, varscan2
- FCER2 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 200/382 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.265); catalogued as rs773775018; called by muse, mutect2, varscan2
- FEN1 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 170/371 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs770209728; called by muse, mutect2, varscan2
- FER1L6 | c.1406dup p.E470Gfs*8 | Frame Shift Ins (INS) | VAF 109/402 reads (27%) | catalogued as rs950533888; called by mutect2, varscan2
- FERD3L | c.218A>G p.D73G | Missense Mutation (SNP) | VAF 228/436 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV51761698; called by muse, varscan2
- FGFRL1 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 334/652 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239043664; called by muse, mutect2, varscan2
- FHIT | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 92/249 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); catalogued as rs202183587, COSV100533058; called by muse, mutect2, varscan2
- FIBCD1 | c.335A>G p.Q112R | Missense Mutation (SNP) | VAF 206/441 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs778578356; called by muse, mutect2, varscan2
- FIG4 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 158/335 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as rs192447225; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FIGNL2 | c.680del p.P227Rfs*5 | Frame Shift Del (DEL) | VAF 211/554 reads (38%) | catalogued as rs1352452891; called by pindel, varscan2
- FKRP | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 201/410 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.38); catalogued as rs1465811690; called by muse, mutect2, varscan2
- FLNB | c.7448A>G p.N2483S | Missense Mutation (SNP) | VAF 130/260 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs145849608; called by muse, mutect2, varscan2
- FMR1NB | c.27G>T p.K9N | Missense Mutation (SNP) | VAF 180/181 reads (99%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as rs1557186482; called by muse, mutect2, varscan2
- FNBP1L | c.1738C>T p.R580W (on ENST00000271234 / NM_001164473.2; = p.R522W on NM_017737.5) | Missense Mutation (SNP) | VAF 151/310 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766179132; called by muse, mutect2, varscan2
- FOXC1 | c.1175C>T p.T392I | Missense Mutation (SNP) | VAF 102/214 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as rs1036201687; called by muse, mutect2, varscan2
- FOXO1 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 189/387 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs146488369; called by muse, mutect2, varscan2
- FOXP4 | c.997G>A p.A333T (on ENST00000307972 / NM_001012426.1; = p.A332T on NM_138457.3) | Missense Mutation (SNP) | VAF 112/260 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.087); catalogued as rs567176815, COSV57218141; called by muse, mutect2, varscan2
- FRMD4A | c.1981G>A p.G661S | Missense Mutation (SNP) | VAF 186/396 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1031730680, COSV62263962; called by muse, mutect2, varscan2
- FSD1 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 196/386 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); catalogued as rs1232364286, COSV99696901; called by muse, mutect2, varscan2
- FUZ | c.1169T>G p.L390R | Missense Mutation (SNP) | VAF 238/460 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1226811597, COSV58241812; called by muse, varscan2
- FYN | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 146/329 reads (44%) | catalogued as COSV57614634; called by muse, varscan2
- FZR1 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 176/351 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs967469604, COSV100553573; called by muse, mutect2, varscan2
- GABRA5 | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 214/422 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100164839; called by muse, mutect2, varscan2
- GABRA5 | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 180/389 reads (46%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.93); catalogued as COSV59486364; called by muse, mutect2, varscan2
- GABRB1 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 217/433 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV54970002; called by muse, mutect2, varscan2
- GAL3ST3 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 283/557 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.316); catalogued as COSV61749159; called by muse, mutect2, varscan2
- GALNT1 | c.113del p.K38Rfs*11 | Frame Shift Del (DEL) | VAF 86/196 reads (44%) | catalogued as rs1225897793; called by mutect2, varscan2
- GALNT12 | c.1472C>T p.T491M | Missense Mutation (SNP) | VAF 110/225 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs267606840, CM094553; ClinVar: risk factor; called by muse, mutect2, varscan2
- GALNT13 | c.1124A>G p.E375G | Missense Mutation (SNP) | VAF 121/222 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV67241439; called by muse, mutect2, varscan2
- GALNT18 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 189/412 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV57144148; called by muse, mutect2, varscan2
- GALP | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 93/269 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.14); catalogued as COSV61999219; called by muse, mutect2, varscan2
- GAS6 | c.449del p.G150Afs*49 | Frame Shift Del (DEL) | VAF 164/392 reads (42%) | catalogued as rs773341392; called by mutect2, pindel, varscan2
- GDF2 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 159/324 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as rs781829279; called by muse, mutect2, varscan2
- GDF7 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 243/496 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV55348334, COSV99694245; called by muse, mutect2, varscan2
- GGTLC1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 334/688 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1217439000, COSV99600526; called by muse, mutect2, varscan2
- GJA9 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 120/276 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as COSV62532737; called by muse, mutect2, varscan2
- GLCE | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 154/334 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs184777253, COSV99962296; called by muse, mutect2, varscan2
- GLI2 | c.2503G>A p.A835T (on ENST00000361492 / NM_001374353.1; = p.A852T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 345/713 reads (48%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.484); catalogued as rs751028726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLRA3 | c.201C>T p.G67= | Splice Region (SNP) | VAF 74/231 reads (32%) | catalogued as rs1220185797; called by muse, mutect2, varscan2
- GNAZ | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 222/486 reads (46%) | catalogued as COSV50737082; called by muse, mutect2, varscan2
- GNB1L | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 265/529 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs149398894; called by muse, mutect2, varscan2
- GOLGA4 | c.4098del p.V1367Lfs*10 | Frame Shift Del (DEL) | VAF 102/241 reads (42%) | catalogued as rs768760517; called by mutect2, varscan2
- GOLGA6A | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 149/725 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs374121270; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 125/224 reads (56%) | catalogued as rs370114090; called by mutect2, varscan2
- GPAT2 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs756153213, COSV64003017; called by muse, mutect2, varscan2
- GPC1 | c.1252G>A p.G418R | Missense Mutation (SNP) | VAF 135/338 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50862730; called by muse, mutect2, varscan2
- GPR150 | c.564del p.S189Rfs*106 | Frame Shift Del (DEL) | VAF 162/451 reads (36%) | catalogued as rs1561375968; called by mutect2, pindel, varscan2
- GPR33 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 182/349 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.102); catalogued as rs1171509258; called by muse, mutect2, varscan2
- GPR34 | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 204/204 reads (100%) | catalogued as rs1269693556, COSV100587546; called by muse, mutect2, varscan2
- GRB7 | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 218/453 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs373351063; called by muse, mutect2, varscan2
- GRIN2A | c.2453C>T p.A818V | Missense Mutation (SNP) | VAF 135/292 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751455326, COSV58061875; called by muse, mutect2, varscan2
- GRIN2D | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 10/279 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1316188370, COSV54382415; called by muse, mutect2
- GRIN3B | c.988G>A p.G330R | Missense Mutation (SNP) | VAF 229/519 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs748625717; called by muse, mutect2, varscan2
- GRM1 | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 189/343 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99269381; called by muse, mutect2, varscan2
- GRM1 | c.3168del p.G1057Vfs*26 | Frame Shift Del (DEL) | VAF 216/620 reads (35%) | catalogued as COSV51118480; called by pindel, varscan2
- GRM3 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 145/272 reads (53%) | catalogued as rs891435292, COSV64467524; called by muse, mutect2, varscan2
- GRM5 | c.3434C>T p.A1145V (on ENST00000305447 / NM_001143831.2; = p.A1113V on NM_000842.4) | Missense Mutation (SNP) | VAF 258/520 reads (50%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1349965240; called by muse, mutect2, varscan2
- GSC | c.184G>C p.V62L | Missense Mutation (SNP) | VAF 328/701 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV53076764; called by muse, mutect2
- GSPT2 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 238/238 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV61213769; called by muse, mutect2, varscan2
- GTF2E2 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 89/181 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs150253885; called by muse, mutect2, varscan2
- H2AC21 | c.107G>C p.R36P | Missense Mutation (SNP) | VAF 205/416 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV58612603; called by muse, mutect2, varscan2
- H3C10 | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.489); catalogued as COSV60798803; called by muse, mutect2, varscan2
- H3C4 | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 110/234 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61911803; called by muse, mutect2, varscan2
- HACD4 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 118/227 reads (52%) | catalogued as rs763725164; called by muse, mutect2, varscan2
- HAS1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 342/710 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV99708328; called by muse, mutect2, varscan2
- HAS3 | c.1624A>G p.K542E | Missense Mutation (SNP) | VAF 156/313 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as rs767900238; called by muse, mutect2, varscan2
- HAUS6 | c.2811_2813del p.E937del | In Frame Del (DEL) | VAF 82/216 reads (38%) | catalogued as rs755821951; called by pindel, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 176/403 reads (44%) | catalogued as rs746547303; called by mutect2, pindel, varscan2
- HDAC1 | c.1402_1404del p.E468del | In Frame Del (DEL) | VAF 135/270 reads (50%) | catalogued as rs771427696; called by pindel, varscan2
- HDAC11 | c.416del p.X139_splice | Splice Site (DEL) | VAF 151/345 reads (44%) | catalogued as rs1192877865; called by mutect2, pindel, varscan2
- HDHD3 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 176/411 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs747591014, COSV53056601; called by muse, mutect2, varscan2
- HEATR5A | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 167/339 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs565318154, COSV66339670; called by muse, mutect2, varscan2
- HECTD4 | c.7861C>T p.Q2621* | Nonsense Mutation (SNP) | VAF 105/217 reads (48%) | catalogued as rs1462575711; called by muse, mutect2, varscan2
- HECW1 | c.2652-1G>T p.X884_splice | Splice Site (SNP) | VAF 69/144 reads (48%) | catalogued as rs751019277, COSV101224151; called by muse, mutect2, varscan2
- HELZ2 | c.2221G>A p.E741K (on ENST00000467148 / NM_001037335.2; = p.E172K on NM_033405.3) | Missense Mutation (SNP) | VAF 266/523 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.68); catalogued as rs114630740; called by muse, mutect2, varscan2
- HIC1 | c.203G>A p.S68N (on ENST00000322941 / NM_001098202.1; = p.S49N on NM_006497.4) | Missense Mutation (SNP) | VAF 222/470 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53967151; called by muse, mutect2, varscan2
- HIC1 | c.541G>A p.A181T (on ENST00000322941 / NM_001098202.1; = p.A162T on NM_006497.4) | Missense Mutation (SNP) | VAF 294/564 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs966282867; called by muse, mutect2, varscan2
- HIVEP2 | c.4845del p.S1616Afs*32 | Frame Shift Del (DEL) | VAF 192/482 reads (40%) | catalogued as COSV50038785; called by mutect2, pindel, varscan2
- HK2 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 135/287 reads (47%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.614); catalogued as rs368353026; called by muse, mutect2, varscan2
- HK2 | c.2600T>C p.L867P | Missense Mutation (SNP) | VAF 112/246 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51876198; called by muse, mutect2
- HLA-DPA1 | c.630G>T p.E210D | Missense Mutation (SNP) | VAF 159/347 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs56119512; called by muse, mutect2, varscan2
- HMX2 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 287/509 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.163); catalogued as rs914122942; called by muse, mutect2, varscan2
- HOXB9 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 255/520 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1472217346, COSV100239469; called by muse, mutect2, varscan2
- HP1BP3 | c.666del p.G223Vfs*35 | Frame Shift Del (DEL) | VAF 120/318 reads (38%) | catalogued as COSV56563564; called by mutect2, pindel, varscan2
- HR | c.3482del p.P1161Lfs*18 | Frame Shift Del (DEL) | VAF 117/286 reads (41%) | catalogued as rs1563615173; called by mutect2, pindel, varscan2
- HRH4 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 178/344 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV56929020; called by muse, mutect2, varscan2
- HSD17B4 | c.1976G>A p.R659H (on ENST00000414835 / NM_001199291.3; = p.R634H on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 110/263 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as rs752768656, COSV56334749; called by muse, mutect2, varscan2
- HSD3B7 | c.543del p.L182Cfs*4 | Frame Shift Del (DEL) | VAF 156/356 reads (44%) | catalogued as COSV52682172; called by mutect2, pindel, varscan2
- HSF1 | c.1248C>T p.D416= | Splice Region (SNP) | VAF 224/330 reads (68%) | catalogued as rs782152652, COSV60047718; called by mutect2, varscan2
- HSPA1A | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 105/371 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.697); catalogued as rs762517250; called by muse, mutect2, varscan2
- HSPB7 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 126/285 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1280039361; called by muse, mutect2, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 96/275 reads (35%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- HYDIN | c.11830C>T p.R3944W | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1353096518, COSV66638801; called by muse, mutect2, varscan2
- ICE1 | c.6004C>T p.R2002W | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770825015, COSV99665223; called by muse, varscan2
- IDUA | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 204/399 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.131); catalogued as rs764394402, COSV56107079; called by muse, mutect2, varscan2
- IFI6 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 257/505 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.419); catalogued as COSV59270214; called by muse, mutect2, varscan2
- IFIT5 | c.1351A>G p.K451E | Missense Mutation (SNP) | VAF 141/253 reads (56%) | SIFT tolerated (0.94); PolyPhen benign (0.129); catalogued as rs1564817717; called by muse, mutect2, varscan2
- IFT140 | c.3331C>T p.Q1111* | Nonsense Mutation (SNP) | VAF 193/414 reads (47%) | catalogued as rs1354876525; called by muse, mutect2, varscan2
- IFT140 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 154/344 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs145551546; called by muse, mutect2, varscan2
- IFT172 | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 206/452 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs779152335, COSV53131510; called by muse, mutect2, varscan2
- IGDCC4 | c.2613dup p.T872Hfs*22 | Frame Shift Ins (INS) | VAF 221/474 reads (47%) | catalogued as rs761621429; called by mutect2, varscan2
- IGF2BP3 | c.905T>A p.I302N | Missense Mutation (SNP) | VAF 90/227 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV51684647; called by muse, mutect2, varscan2
- IGFALS | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 180/412 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51905444; called by muse, mutect2, varscan2
- IGFBP1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 234/542 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs376937815; called by muse, mutect2, varscan2
- IHH | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 258/522 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as rs745408084, COSV55392903; called by muse, mutect2, varscan2
- IKZF5 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 166/340 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs745563418, COSV64397534; called by muse, mutect2, varscan2
- IL12RB2 | c.773G>T p.R258I | Missense Mutation (SNP) | VAF 118/255 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV52025704; called by muse, mutect2, varscan2
- IL17RD | c.2210C>T p.A737V | Missense Mutation (SNP) | VAF 133/281 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.686); catalogued as rs1362044881; called by muse, mutect2, varscan2
- IL9R | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 241/347 reads (69%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.625); catalogued as rs768204373; called by muse, varscan2
- IMPG1 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 159/330 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs137915302; called by muse, mutect2, varscan2
- ING3 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 164/383 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV59952023; called by muse, mutect2, varscan2
- INPP1 | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 133/318 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as rs777831500, COSV59416213; called by muse, mutect2, varscan2
- INPP4B | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 82/183 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374251810; called by muse, mutect2, varscan2
- INPP5F | c.2488_2490del p.S830del | In Frame Del (DEL) | VAF 124/258 reads (48%) | catalogued as rs752816097; called by pindel, varscan2
- INPPL1 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 124/290 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs200043222, COSV53358151; called by muse, mutect2, varscan2
- INTS1 | c.3286C>T p.R1096C | Missense Mutation (SNP) | VAF 207/382 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373184951; called by muse, mutect2, varscan2
- IPO5 | c.2836G>A p.E946K | Missense Mutation (SNP) | VAF 112/208 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs1335509101; called by muse, mutect2, varscan2
- IRX1 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 317/655 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100116367; called by muse, mutect2, varscan2
- IRX1 | c.1028C>A p.A343E | Missense Mutation (SNP) | VAF 315/658 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs956423982; called by muse, mutect2, varscan2
- IRX2 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 270/590 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV100121768; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 109/236 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as rs749725763, COSV59349826; called by muse, varscan2
- ITGA11 | c.1828G>T p.G610W | Missense Mutation (SNP) | VAF 164/375 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100241953, COSV59878632; called by muse, mutect2, varscan2
- ITGA9 | c.973del p.A325Pfs*30 | Frame Shift Del (DEL) | VAF 183/466 reads (39%) | catalogued as rs1193450968; called by mutect2, pindel, varscan2
- ITGB3 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 107/230 reads (47%) | catalogued as rs75427428, CM984088, COSV101457551; called by muse, mutect2, varscan2
- ITPR3 | c.6686C>T p.A2229V | Missense Mutation (SNP) | VAF 89/198 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as rs770070136; called by muse, varscan2
- JAG1 | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 139/314 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs138470284; called by muse, mutect2, varscan2
- JAG1 | c.270del p.C92Afs*69 | Frame Shift Del (DEL) | VAF 270/581 reads (46%) | catalogued as CD062180, CX062302; called by mutect2, varscan2
- JAG2 | c.1252del p.A418Pfs*24 | Frame Shift Del (DEL) | VAF 114/301 reads (38%) | catalogued as COSV100079006; called by mutect2, pindel, varscan2
- JAK1 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 144/317 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as rs774002055; called by muse, mutect2, varscan2
- JAML | c.527G>A p.R176H (on ENST00000356289 / NM_001098526.2; = p.R166H on NM_153206.3) | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765722769; called by muse, mutect2, varscan2
- JARID2 | c.664G>T p.G222W | Missense Mutation (SNP) | VAF 136/263 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59184943; called by muse, mutect2, varscan2
- JMY | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 290/604 reads (48%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as rs960144929; called by muse, mutect2, varscan2
- KALRN | c.2632A>G p.N878D | Missense Mutation (SNP) | VAF 158/317 reads (50%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as rs1032315445; called by muse, mutect2, varscan2
- KAZALD1 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 232/449 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs142623306; called by muse, mutect2, varscan2
- KBTBD4 | c.1156dup p.E386Gfs*4 | Frame Shift Ins (INS) | VAF 122/303 reads (40%) | catalogued as rs756343868, COSV58597480; called by mutect2, varscan2
- KCNB2 | c.20del p.P7Rfs*3 | Frame Shift Del (DEL) | VAF 97/400 reads (24%) | catalogued as COSV73049036; called by mutect2, pindel, varscan2
- KCNC1 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 217/421 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376576774; called by muse, mutect2, varscan2
- KCNG2 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 118/237 reads (50%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as rs1456735768, COSV60269417; called by muse, varscan2
- KCNG2 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 285/589 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs759269029, COSV60267664; called by muse, mutect2, varscan2
- KCNMA1 | c.1928G>A p.R643H | Missense Mutation (SNP) | VAF 121/266 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.522); catalogued as COSV54245432; called by muse, mutect2, varscan2
- KCNT1 | c.2039C>T p.T680M (on ENST00000488444; = p.T699M on NM_020822.3) | Missense Mutation (SNP) | VAF 275/579 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.238); catalogued as rs538197009, COSV53700849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCTD21 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 131/378 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288115947; called by muse, mutect2, varscan2
- KCTD3 | c.2416del p.S806Vfs*16 | Frame Shift Del (DEL) | VAF 172/344 reads (50%) | catalogued as rs754600318; called by mutect2, varscan2
- KDM5D | c.3454C>T p.R1152C | Missense Mutation (SNP) | VAF 209/209 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs761610918, COSV58737035; called by muse, mutect2, varscan2
- KIAA0319L | c.1595G>A p.G532D | Missense Mutation (SNP) | VAF 146/286 reads (51%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.699); catalogued as rs750538375; called by muse, mutect2, varscan2
- KIAA1549 | c.3974G>A p.R1325H | Missense Mutation (SNP) | VAF 161/343 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs986194090, COSV54319747, COSV99650435; called by muse, mutect2, varscan2
- KIF15 | c.567G>T p.E189D | Missense Mutation (SNP) | VAF 140/295 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58163886; called by muse, mutect2, varscan2
- KIF16B | c.2860_2862del p.E954del | In Frame Del (DEL) | VAF 166/338 reads (49%) | catalogued as rs780099415; called by pindel, varscan2
- KIF24 | c.2579C>T p.T860M | Missense Mutation (SNP) | VAF 145/344 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs753178804; called by muse, mutect2, varscan2
- KIF24 | c.2414C>T p.P805L | Missense Mutation (SNP) | VAF 179/350 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs373496914; called by muse, mutect2, varscan2
- KIF26B | c.5089G>A p.A1697T | Missense Mutation (SNP) | VAF 272/578 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV63636080; called by muse, varscan2
- KIF2C | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 170/378 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as rs779674363, COSV100945566; called by muse, mutect2
- KIF7 | c.3778dup p.R1260Pfs*26 | Frame Shift Ins (INS) | VAF 185/460 reads (40%) | catalogued as rs777426943; called by mutect2, pindel, varscan2
- KIZ | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 126/266 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs769511209; called by muse, varscan2
- KLC2 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 110/227 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1425226247, COSV100270648; called by muse, mutect2, varscan2
- KLHL24 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 138/264 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs773448712, COSV54426935; called by muse, mutect2, varscan2
- KLHL25 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 213/433 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as rs759868504; called by muse, mutect2, varscan2
- KLHL29 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 315/657 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.022); catalogued as rs923886016, COSV99942776; called by muse, mutect2, varscan2
- KLHL36 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 89/213 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.885); catalogued as rs776360460; called by muse, mutect2, varscan2
- KLHL40 | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 34/518 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55135055; called by muse, mutect2
- KMT2D | c.13588G>A p.D4530N | Missense Mutation (SNP) | VAF 239/501 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs768143170, COSV56475456; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KNL1 | c.1700A>C p.H567P (on ENST00000346991 / NM_170589.5; = p.H541P on NM_144508.5) | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as rs1490208875; called by muse, mutect2
- KRT71 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 143/288 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57290349; called by muse, mutect2, varscan2
- KRT73 | c.308dup p.I104Yfs*21 | Frame Shift Ins (INS) | VAF 188/480 reads (39%) | catalogued as rs1406947958; called by mutect2, pindel, varscan2
- KRT86 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 238/598 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs1335005945; called by muse, mutect2, varscan2
- KRTAP9-8 | c.71T>G p.V24G | Missense Mutation (SNP) | VAF 41/796 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.152); catalogued as COSV99565814; called by muse, mutect2
- LAMA1 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 111/211 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs757753574; called by muse, mutect2, varscan2
- LAMA5 | c.8107C>T p.R2703C | Missense Mutation (SNP) | VAF 231/460 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs776281626, COSV104386501; called by muse, varscan2
- LAMA5 | c.5512C>T p.R1838W | Missense Mutation (SNP) | VAF 151/332 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as rs200449284; called by muse, mutect2, varscan2
- LAMB2 | c.3856G>A p.V1286M | Missense Mutation (SNP) | VAF 227/435 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as rs768658939; called by muse, mutect2, varscan2
- LARGE1 | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 146/286 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs150325234; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 80/230 reads (35%) | catalogued as COSV60222740; called by pindel, varscan2
- LIMK1 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 220/468 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs1406801488; called by muse, mutect2, varscan2
- LIMK2 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 128/253 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.262); catalogued as rs371699959; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 322/685 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs530958757; called by muse, mutect2, varscan2
- LINC02218 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 153/319 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs760674283; called by muse, mutect2, varscan2
- LINGO3 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 241/480 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.446); catalogued as rs764806993; called by muse, mutect2, varscan2
- LIPE | c.2939T>C p.L980P | Missense Mutation (SNP) | VAF 101/285 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188486431; called by muse, mutect2, varscan2
- LIPH | c.1093C>T p.H365Y | Missense Mutation (SNP) | VAF 98/228 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs1396664855, COSV99956116; called by muse, mutect2
- LLGL1 | c.2818C>T p.R940W | Missense Mutation (SNP) | VAF 176/357 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs757193789; called by muse, mutect2, varscan2
- LONP2 | c.1771C>A p.R591S | Missense Mutation (SNP) | VAF 107/240 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV53522648; called by muse, mutect2, varscan2
- LONRF2 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 243/488 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.072); catalogued as rs561134585; called by muse, mutect2, varscan2
- LOXHD1 | c.6233C>T p.A2078V (on ENST00000642948; = p.A2016V on NM_144612.7) | Missense Mutation (SNP) | VAF 152/343 reads (44%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.493); catalogued as COSV56071723; called by muse, mutect2, varscan2
- LRFN1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 265/527 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202051401; called by muse, mutect2, varscan2
- LRIT1 | c.52del p.Q18Rfs*26 | Frame Shift Del (DEL) | VAF 169/394 reads (43%) | catalogued as rs759958964; called by mutect2, pindel, varscan2
- LRP1B | c.4981C>T p.R1661C | Missense Mutation (SNP) | VAF 143/288 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs150231464, COSV101258278; called by muse, mutect2, varscan2
- LRP3 | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 255/542 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs772915222, COSV53504816; called by muse, mutect2, varscan2
- LRP5 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 152/285 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs773665226, COSV53725366; called by muse, mutect2, varscan2
- LRRC4 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 191/398 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.906); catalogued as rs766893575; called by muse, mutect2, varscan2
- LRRC66 | c.760A>G p.N254D | Missense Mutation (SNP) | VAF 180/374 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs201366554; called by muse, mutect2, varscan2
- LRRD1 | c.2249G>A p.R750H | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1429064147, COSV58467806; called by muse, mutect2, varscan2
- LRRN4 | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 195/396 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs752197478; called by muse, mutect2, varscan2
- LRRTM1 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 279/557 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs921691242; called by muse, mutect2, varscan2
- LRRTM2 | c.975G>A p.W325* | Nonsense Mutation (SNP) | VAF 118/282 reads (42%) | catalogued as rs1045330892; called by muse, mutect2, varscan2
- LSP1 | c.322del p.Q108Sfs*31 | Frame Shift Del (DEL) | VAF 141/365 reads (39%) | catalogued as rs752018434; called by mutect2, pindel, varscan2
- LTBP3 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 233/441 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs747180627, COSV57243337; called by muse, mutect2, varscan2
- LTBP4 | c.4775G>A p.R1592H (on ENST00000308370 / NM_001042544.1; = p.R1555H on NM_003573.2) | Missense Mutation (SNP) | VAF 202/445 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs562237303; called by muse, mutect2, varscan2
- MACF1 | c.2890C>T p.R964C | Missense Mutation (SNP) | VAF 118/260 reads (45%) | catalogued as rs1241320476; called by muse, mutect2, varscan2
- MACF1 | c.18718G>A p.E6240K (on ENST00000372915; = p.E4285K on NM_012090.5) | Missense Mutation (SNP) | VAF 140/326 reads (43%) | catalogued as rs147673829; called by muse, mutect2, varscan2
- MAEL | c.132G>A p.A44= | Splice Region (SNP) | VAF 114/208 reads (55%) | catalogued as rs1296702154; called by muse, varscan2
- MAG | c.1835C>T p.T612M | Missense Mutation (SNP) | VAF 179/371 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs201203320; called by muse, mutect2, varscan2
- MAGEB10 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 200/203 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV63312482; called by muse, mutect2, varscan2
- MAGI3 | c.4072dup p.I1358Nfs*6 | Frame Shift Ins (INS) | VAF 112/253 reads (44%) | catalogued as rs1278102315; called by mutect2, varscan2
- MAMDC4 | c.2021A>G p.H674R (on ENST00000445819; = p.H595R on NM_206920.3) | Missense Mutation (SNP) | VAF 236/467 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as rs530111668; called by muse, mutect2, varscan2
- MAN2A2 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as rs997489885, COSV64637077; called by muse, mutect2
- MAP1B | c.2398G>A p.G800S | Missense Mutation (SNP) | VAF 194/426 reads (46%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.003); catalogued as rs778950672, COSV99702156; called by muse, mutect2, varscan2
- MAP1B | c.7003G>A p.A2335T | Missense Mutation (SNP) | VAF 122/225 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs370354996; called by muse, mutect2, varscan2
- MAP2 | c.4420dup p.T1474Nfs*22 | Frame Shift Ins (INS) | VAF 106/244 reads (43%) | catalogued as rs1476495251; called by mutect2, varscan2
- MAP2K6 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1168475716, COSV63005280; called by muse, mutect2, varscan2
- MAP3K13 | c.2737G>A p.V913M | Missense Mutation (SNP) | VAF 163/313 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs759993681, COSV99408264; called by muse, mutect2, varscan2
- MAP4 | c.301A>G p.T101A | Missense Mutation (SNP) | VAF 91/194 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs760375075; called by muse, mutect2, varscan2
- MAPK8IP3 | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 111/241 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs373591543; called by muse, mutect2, varscan2
- MARCHF5 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868617911, COSV62768780; called by muse, mutect2, varscan2
- MARK3 | c.158T>C p.I53T | Missense Mutation (SNP) | VAF 124/303 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1436509322; called by muse, mutect2, varscan2
- MARK3 | c.2083C>T p.R695C (on ENST00000429436 / NM_001128918.3; = p.R671C on NM_002376.6) | Missense Mutation (SNP) | VAF 188/392 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs776353754; called by muse, mutect2, varscan2
- MARK4 | c.1553del p.P518Rfs*102 | Frame Shift Del (DEL) | VAF 137/352 reads (39%) | catalogued as COSV53469249; called by mutect2, pindel, varscan2
- MASP2 | c.1592A>G p.N531S | Missense Mutation (SNP) | VAF 100/230 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); catalogued as rs201361542; called by muse, mutect2, varscan2
- MAST2 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 139/289 reads (48%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.833); catalogued as rs1264605502; called by muse, mutect2, varscan2
- MAST2 | c.3820del p.R1274Dfs*9 | Frame Shift Del (DEL) | VAF 188/381 reads (49%) | catalogued as rs1405419593; called by mutect2, varscan2
- MAST4 | c.7732G>A p.V2578M (on ENST00000403625 / NM_001164664.2; = p.V2389M on NM_015183.3) | Missense Mutation (SNP) | VAF 197/382 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as rs1298362202; called by muse, mutect2, varscan2
- MAT1A | c.964A>G p.I322V | Missense Mutation (SNP) | VAF 95/178 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1057517759, CM106330; called by muse, mutect2, varscan2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 54/118 reads (46%) | catalogued as rs762648935; called by mutect2, varscan2
- MC4R | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 189/400 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV55351496; called by muse, mutect2, varscan2
- MCCD1 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 212/454 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs774776866; called by muse, mutect2, varscan2
- MCHR2 | c.196del p.T66Qfs*18 | Frame Shift Del (DEL) | VAF 134/303 reads (44%) | catalogued as rs774746204; called by mutect2, pindel, varscan2
- MCM3AP | c.5585C>T p.A1862V | Missense Mutation (SNP) | VAF 151/287 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs772612320, COSV52442791; called by muse, mutect2, varscan2
- MCM6 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765220170, COSV51469449; called by muse, mutect2, varscan2
- MDN1 | c.15322C>T p.R5108C | Missense Mutation (SNP) | VAF 98/291 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs574322414, COSV65523482; called by muse, mutect2, varscan2
- MED12L | c.5603C>T p.P1868L | Missense Mutation (SNP) | VAF 216/425 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs775879977; called by muse, mutect2, varscan2
- METTL11B | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 184/354 reads (52%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs1181492114; called by muse, mutect2, varscan2
- MFSD6 | c.1768G>A p.G590R | Missense Mutation (SNP) | VAF 117/232 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1250958313; called by muse, mutect2, varscan2
- MGAT1 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 257/535 reads (48%) | PolyPhen benign (0.003); catalogued as rs201350610; called by muse, mutect2, varscan2
- MIA2 | c.2162del p.P721Hfs*30 | Frame Shift Del (DEL) | VAF 102/258 reads (40%) | catalogued as rs780386330; called by mutect2, pindel, varscan2
- MIA3 | c.2977del p.M993Cfs*14 | Frame Shift Del (DEL) | VAF 103/253 reads (41%) | catalogued as COSV60509642; called by mutect2, pindel, varscan2
- MINK1 | c.1130A>T p.Q377L | Missense Mutation (SNP) | VAF 208/450 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs992035569; called by mutect2, varscan2
- MIXL1 | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 130/286 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100830822; called by muse, mutect2, varscan2
- MMP11 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 258/525 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs1420883362; called by muse, varscan2
- MOGS | c.1267_1269del p.K423del | In Frame Del (DEL) | VAF 153/352 reads (43%) | catalogued as rs1422713925; called by mutect2, pindel, varscan2
- MOS | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 172/737 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV61336532; called by muse, mutect2, varscan2
- MPP6 | c.917del p.K306Rfs*4 | Frame Shift Del (DEL) | VAF 64/129 reads (50%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MPPED2 | c.787G>A p.G263S | Missense Mutation (SNP) | VAF 99/212 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs923968534, COSV100813091; called by muse, mutect2, varscan2
- MRPL32 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 153/365 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1269710787; called by muse, mutect2, varscan2
- MS4A18 | c.676G>A p.A226T (on ENST00000398983; = p.A228T on NM_001354471.1) | Missense Mutation (SNP) | VAF 156/306 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs960858474; called by muse, mutect2, varscan2
- MSH6 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 140/255 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.243); catalogued as rs63750440, COSV52277030; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSI1 | c.77del p.G26Dfs*21 | Frame Shift Del (DEL) | VAF 233/542 reads (43%) | catalogued as rs1490523146; called by mutect2, pindel, varscan2
- MTF1 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 161/331 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs774690246; called by muse, mutect2, varscan2
- MTMR3 | c.1264del p.Q422Rfs*17 | Frame Shift Del (DEL) | VAF 181/417 reads (43%) | catalogued as rs1569049307, COSV60306865; called by mutect2, pindel, varscan2
- MTNR1B | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 303/582 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs764087177, COSV57068015; called by muse, mutect2, varscan2
- MUC4 | c.13673G>A p.R4558H (on ENST00000463781 / NM_018406.7; = p.R322H on NM_004532.6) | Missense Mutation (SNP) | VAF 279/575 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.917); catalogued as rs756663963, COSV57765660; called by muse, varscan2
- MUC4 | c.2707G>A p.A903T | Missense Mutation (SNP) | VAF 22/817 reads (3%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.494); catalogued as rs1438580385; called by muse, mutect2
- MXD4 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 212/456 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1363301183; called by muse, mutect2, varscan2
- MXRA5 | c.6115C>T p.R2039C | Missense Mutation (SNP) | VAF 321/321 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140758671, COSV54242569; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 269/638 reads (42%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYO15A | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 221/411 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1034382621; called by muse, mutect2, varscan2
- MYO15B | c.1752del p.H585Tfs*92 | Frame Shift Del (DEL) | VAF 263/623 reads (42%) | catalogued as rs1192198131; called by mutect2, pindel, varscan2
- MYO15B | c.3820C>T p.R1274W | Missense Mutation (SNP) | VAF 216/462 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); catalogued as rs779761451; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 74/181 reads (41%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO1G | c.2729C>T p.A910V | Missense Mutation (SNP) | VAF 142/333 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs1208746512; called by muse, mutect2, varscan2
- MYOC | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 190/446 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50676004; called by muse, mutect2, varscan2
- MYORG | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 236/464 reads (51%) | SIFT tolerated (0.46); PolyPhen benign (0.021); catalogued as rs768887124, COSV52627720; called by muse, mutect2
- MYOT | c.185T>C p.I62T | Missense Mutation (SNP) | VAF 311/548 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.237); catalogued as rs756265501; called by muse, mutect2, varscan2
- NAA80 | c.347C>T p.A116V (on ENST00000417393 / NM_001200018.2; = p.A138V on NM_012191.4) | Missense Mutation (SNP) | VAF 307/650 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.492); catalogued as rs1490290422; called by muse, mutect2, varscan2
- NAP1L2 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV100999200; called by muse, mutect2, varscan2
- NAV2 | c.1409G>A p.R470H (on ENST00000396087 / NM_001244963.2; = p.R447H on NM_145117.5) | Missense Mutation (SNP) | VAF 228/486 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs942158475, COSV62324496; called by muse, varscan2
- NAV2 | c.5378G>A p.R1793H (on ENST00000396087 / NM_001244963.2; = p.R1737H on NM_145117.5) | Missense Mutation (SNP) | VAF 149/351 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764843299, COSV60657909; called by muse, mutect2, varscan2
- NBEAL2 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 205/429 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs201277818; called by muse, mutect2, varscan2
- NBEAL2 | c.4730C>T p.A1577V | Missense Mutation (SNP) | VAF 193/380 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.27); catalogued as rs753685160, COSV99434198; called by muse, mutect2, varscan2
- NBEAL2 | c.5261G>A p.R1754Q | Missense Mutation (SNP) | VAF 155/309 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as rs746431370, COSV52763136; called by muse, mutect2, varscan2
- NCAN | c.3826C>T p.R1276C | Missense Mutation (SNP) | VAF 189/374 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs763221106; called by muse, mutect2, varscan2
- NCAPD2 | c.2026C>T p.R676C | Missense Mutation (SNP) | VAF 206/436 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765575100, COSV59698881; called by muse, mutect2, varscan2
- NCAPD2 | c.2508del p.F837Sfs*36 | Frame Shift Del (DEL) | VAF 114/314 reads (36%) | catalogued as rs772347389; called by mutect2, pindel, varscan2
- NCAPH | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 156/364 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs776324768, COSV53636574; called by muse, mutect2, varscan2
- NCKIPSD | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 167/387 reads (43%) | catalogued as rs781582926; called by muse, mutect2, varscan2
- NCOR2 | c.5872G>A p.A1958T | Missense Mutation (SNP) | VAF 263/564 reads (47%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.015); catalogued as rs753831136, COSV62297190; called by muse, mutect2, varscan2
- NDUFA10 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 125/276 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs558134843, COSV53153406; called by muse, mutect2, varscan2
- NEB | c.13385C>T p.A4462V | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs201529683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEB | c.11281G>A p.A3761T | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs750705899; called by muse, mutect2, varscan2
- NECTIN1 | c.382A>G p.T128A | Missense Mutation (SNP) | VAF 163/312 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50599247; called by muse, mutect2, varscan2
- NEFL | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 210/426 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV55337727; called by muse, mutect2, varscan2
- NEK4 | c.1975C>T p.R659W | Missense Mutation (SNP) | VAF 139/253 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs200698397, COSV99238164; called by muse, mutect2, varscan2
- NELFCD | c.998C>T p.P333L (on ENST00000602795; = p.P315L on NM_198976.4) | Missense Mutation (SNP) | VAF 112/243 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1196893838, COSV99413691; called by muse, mutect2, varscan2
- NELFE | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 29/863 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs772078692, COSV99064754; called by muse, mutect2
- NEO1 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 88/206 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); catalogued as COSV99981311; called by muse, varscan2
- NEXN | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 100/231 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs758055856, COSV53942514; called by muse, mutect2, varscan2
- NFE2L1 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 235/467 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1192084871, COSV62583270; called by muse, mutect2, varscan2
- NFXL1 | c.1883T>C p.L628S | Missense Mutation (SNP) | VAF 102/212 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV61200118; called by muse, mutect2, varscan2
- NHS | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 222/222 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752841030, COSV66273449; called by muse, mutect2, varscan2
- NLRC3 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 200/429 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs777729538; called by muse, mutect2, varscan2
- NLRP12 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 204/418 reads (49%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as rs1307240172; called by muse, varscan2
- NLRX1 | c.2074G>A p.A692T | Missense Mutation (SNP) | VAF 203/384 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs375007674; called by muse, mutect2, varscan2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 187/423 reads (44%) | catalogued as rs1282346576; called by mutect2, pindel, varscan2
- NOTCH1 | c.5884C>T p.R1962C | Missense Mutation (SNP) | VAF 211/427 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1186696796, COSV53036726; called by muse, mutect2, varscan2
- NOTCH3 | c.2330del p.P777Rfs*83 | Frame Shift Del (DEL) | VAF 222/555 reads (40%) | catalogued as COSV54635242, COSV54651609; called by mutect2, pindel, varscan2
- NPR1 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 294/635 reads (46%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs994822671, COSV64141077; called by muse, mutect2, varscan2
- NPR1 | c.2972G>A p.R991H | Missense Mutation (SNP) | VAF 157/325 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369856492, COSV104424973; called by muse, mutect2, varscan2
- NPY4R | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 82/320 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs149694580; called by muse, mutect2, varscan2
- NRG1 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 119/245 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.404); catalogued as rs367543160, COSV55163583; ClinVar: not provided; called by muse, mutect2, varscan2
- NRG3 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as rs1423852237; called by muse, varscan2
- NRL | c.371A>G p.Q124R | Missense Mutation (SNP) | VAF 128/313 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as rs764142151; called by muse, mutect2, varscan2
- NRN1L | c.25T>C p.C9R | Missense Mutation (SNP) | VAF 218/482 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1044247559, COSV59302081; called by mutect2, varscan2
- NRXN3 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 165/320 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as rs765195947; called by muse, mutect2, varscan2
- NUB1 | c.990del p.K330Nfs*2 | Frame Shift Del (DEL) | VAF 164/302 reads (54%) | catalogued as rs760102115; called by mutect2, varscan2
- NUP93 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 110/226 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs34670294; called by muse, mutect2, varscan2
- NYX | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 359/359 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs746330892; called by muse, mutect2, varscan2
- OBSCN | c.4091C>T p.A1364V | Missense Mutation (SNP) | VAF 138/287 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.227); catalogued as rs1191199702, COSV52835458; called by muse, mutect2, varscan2
- OBSL1 | c.5162T>C p.V1721A | Missense Mutation (SNP) | VAF 210/499 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); catalogued as rs1180844567; called by muse, mutect2, varscan2
- OCA2 | c.2462G>A p.C821Y | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs756885633; called by muse, mutect2, varscan2
- OLFML2A | c.1486G>A p.V496M | Missense Mutation (SNP) | VAF 38/330 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763392465, COSV56585734; called by muse, mutect2, varscan2
- OLFML2B | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 114/217 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); catalogued as rs144547147; called by muse, mutect2, varscan2
- OLFML2B | c.365del p.P122Hfs*24 | Frame Shift Del (DEL) | VAF 206/512 reads (40%) | catalogued as COSV99668832; called by mutect2, pindel, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 166/427 reads (39%) | catalogued as rs753966040; called by mutect2, pindel, varscan2
- OR10A6 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 192/408 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV59164913; called by muse, mutect2, varscan2
- OR2A14 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 144/294 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.528); catalogued as rs753671195, COSV68718177; called by muse, varscan2
- OR2AE1 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 147/278 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200998386; called by muse, mutect2, varscan2
- OR2L13 | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 143/308 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0.024); catalogued as COSV99050199; called by muse, mutect2, varscan2
- OR2T4 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 91/281 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1427398381; called by muse, mutect2, varscan2
- OR2T8 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 55/93 reads (59%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs757973856, COSV60662474; called by muse, mutect2, varscan2
- OR4A16 | c.193T>A p.S65T | Missense Mutation (SNP) | VAF 164/359 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV100125265; called by muse, mutect2, varscan2
- OR4D2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 150/344 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs142058863, COSV101613850; called by muse, mutect2, varscan2
- OR51M1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 189/352 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs776850628, COSV60785098; called by muse, mutect2, varscan2
- OR52A5 | c.194del p.L65Wfs*20 | Frame Shift Del (DEL) | VAF 282/397 reads (71%) | catalogued as rs762677866, COSV100263457; called by mutect2, pindel, varscan2
- OR52B6 | c.506G>A p.S169N | Missense Mutation (SNP) | VAF 206/373 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as rs1285152531, COSV100798486; called by muse, mutect2, varscan2
- OR5R1 | c.366C>A p.C122* | Nonsense Mutation (SNP) | VAF 110/224 reads (49%) | catalogued as COSV100393355; called by muse, mutect2, varscan2
- OR6S1 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 141/320 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV104413487; called by muse, mutect2, varscan2
- OR7G2 | c.478del p.R160Afs*6 | Frame Shift Del (DEL) | VAF 187/458 reads (41%) | catalogued as COSV100560490, COSV59687536; called by mutect2, pindel, varscan2
- ORAI3 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 195/398 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs747434658; called by muse, mutect2, varscan2
- ORC3 | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 53/110 reads (48%) | catalogued as rs780488879, COSV57642535; called by muse, mutect2, varscan2
- OTUD7A | c.2312del p.P771Rfs*216 (on ENST00000307050 / NM_001382637.1; = p.P764Rfs*216 on NM_130901.3) | Frame Shift Del (DEL) | VAF 72/160 reads (45%) | catalogued as rs1258615864; called by mutect2, pindel, varscan2
- P2RY1 | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 122/250 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV59309607; called by muse, mutect2, varscan2
- P3H1 | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 204/402 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs779744195, COSV52531375; called by muse, varscan2
- P3H2 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 233/476 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.267); catalogued as rs778614714; called by mutect2, varscan2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 109/230 reads (47%) | catalogued as rs763394045; called by mutect2, varscan2
- PABPC4 | c.1494C>T p.G498= | Splice Region (SNP) | VAF 113/242 reads (47%) | catalogued as rs373025595; called by muse, mutect2, varscan2
- PAK4 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 135/301 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs988897964, COSV58944787; called by muse, varscan2
- PAN2 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 173/369 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1468575196, COSV99228381; called by muse, mutect2, varscan2
- PARD3 | c.1366del p.I456* | Frame Shift Del (DEL) | VAF 218/220 reads (99%) | catalogued as rs1484598500; called by mutect2, varscan2
- PARP1 | c.1519dup p.S507Kfs*14 | Frame Shift Ins (INS) | VAF 128/279 reads (46%) | catalogued as rs1159330096; called by mutect2, varscan2
- PARP6 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as rs769021644; called by muse, mutect2, varscan2
- PATL1 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 138/289 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1565134624, COSV55689594; called by muse, mutect2, varscan2
- PAX5 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 148/322 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as rs1323551948, COSV100814199, COSV100814676; called by muse, mutect2, varscan2
- PCDH10 | c.2497G>A p.D833N | Missense Mutation (SNP) | VAF 194/370 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV52105717; called by muse, mutect2, varscan2
- PCDH17 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 225/494 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1375857261, COSV64972185, COSV64973052, COSV64974497; called by muse, varscan2
- PCDH7 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 32/530 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as COSV62341622; called by muse, mutect2
- PCDH8 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 307/641 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as rs1297381936, COSV58813987; called by muse, mutect2, varscan2
- PCDHA4 | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 208/417 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as rs147908793; called by muse, mutect2, varscan2
- PCDHA7 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 31/711 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV100971942; called by muse, mutect2
- PCDHB15 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 242/517 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.022); catalogued as COSV50947485; called by muse, mutect2, varscan2
- PCDHB6 | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 275/648 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50689487; called by muse, mutect2, varscan2
- PCDHGA10 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 238/521 reads (46%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.019); catalogued as rs1561752050, COSV53953649; called by muse, mutect2, varscan2
- PCDHGA8 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 269/615 reads (44%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.007); catalogued as rs367855808, COSV53994657; called by muse, mutect2, varscan2
- PCDHGB5 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 171/442 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV53926615; called by muse, varscan2
- PCDHGC5 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 195/372 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs561792279, COSV99338961; called by muse, mutect2, varscan2
- PCK2 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 159/367 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs551184706, COSV53748018; called by muse, mutect2, varscan2
- PCM1 | c.4196G>A p.R1399H | Missense Mutation (SNP) | VAF 124/308 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs201845791, COSV59586820; called by muse, mutect2, varscan2
- PCNT | c.9010T>C p.W3004R | Missense Mutation (SNP) | VAF 110/233 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1343602042; called by muse, mutect2, varscan2
- PDE3A | c.3032C>A p.P1011H | Missense Mutation (SNP) | VAF 185/375 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62973545; called by muse, mutect2, varscan2
- PDE8B | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 148/307 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.934); catalogued as rs747059922, COSV53732486, COSV53733876; called by muse, mutect2, varscan2
- PDHA2 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 172/324 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs267600306, COSV54776945; called by muse, varscan2
- PDHA2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 145/319 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54781086; called by muse, varscan2
- PDLIM5 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 120/248 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs755501291; called by muse, mutect2, varscan2
- PDP1 | c.480_481del p.F160Lfs*11 | Frame Shift Del (DEL) | VAF 126/595 reads (21%) | catalogued as rs1159542570; called by mutect2, pindel, varscan2
- PDP2 | c.1543G>A p.V515M | Missense Mutation (SNP) | VAF 126/275 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs370083121; called by muse, mutect2, varscan2
- PER1 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 215/423 reads (51%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.813); catalogued as rs781296535; called by muse, mutect2, varscan2
- PEX5L | c.614C>A p.S205* | Nonsense Mutation (SNP) | VAF 110/211 reads (52%) | catalogued as COSV55850133; called by muse, mutect2, varscan2
- PFKL | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 252/494 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs776396229, COSV100827018; called by muse, mutect2, varscan2
- PGLYRP3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 118/279 reads (42%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.97); catalogued as rs369979237; called by muse, mutect2, varscan2
- PGR | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 242/517 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.39); catalogued as rs1349242903; called by muse, mutect2, varscan2
- PHACTR3 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 264/513 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1400091114; called by muse, mutect2, varscan2
- PHACTR3 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 140/268 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs370673509, COSV63031491; called by muse, varscan2
- PHGR1 | c.109del p.H37Tfs*71 | Frame Shift Del (DEL) | VAF 48/372 reads (13%) | catalogued as rs1264440278; called by mutect2*, varscan2
- PHLPP1 | c.795del p.E266Rfs*87 | Frame Shift Del (DEL) | VAF 276/654 reads (42%) | catalogued as rs1175094073; called by mutect2, pindel, varscan2
- PHLPP2 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 190/378 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142034690; called by muse, mutect2, varscan2
- PIAS3 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 134/300 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV57907201; called by muse, mutect2, varscan2
- PIGN | c.2750C>T p.T917M | Missense Mutation (SNP) | VAF 128/243 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs61755364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIGT | c.1043del p.P348Qfs*11 | Frame Shift Del (DEL) | VAF 130/302 reads (43%) | catalogued as rs749895437; called by mutect2, pindel, varscan2
- PIK3C2B | c.4378G>A p.A1460T | Missense Mutation (SNP) | VAF 144/310 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs866176171, COSV65810477; called by muse, mutect2, varscan2
- PIK3CB | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 103/199 reads (52%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.523); catalogued as rs1217537873, COSV56683158; called by muse, mutect2, varscan2
- PIK3CG | c.355C>A p.L119M | Missense Mutation (SNP) | VAF 218/424 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV63255337; called by muse, mutect2, varscan2
- PIN1 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 152/336 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185534250; called by muse, varscan2
- PITPNM1 | c.864del p.D289Mfs*80 | Frame Shift Del (DEL) | VAF 254/660 reads (38%) | catalogued as COSV62707624; called by pindel, varscan2
- PKD1 | c.7390C>T p.R2464C | Missense Mutation (SNP) | VAF 289/627 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); catalogued as rs762786891, COSV99236875; called by muse, mutect2, varscan2
- PKD1L1 | c.3787A>G p.M1263V | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1341700569; called by muse, mutect2
- PKD2 | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 78/183 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs770609334, CM1413568, COSV52936798, COSV52941840; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLA2R1 | c.4119del p.G1374Afs*32 | Frame Shift Del (DEL) | VAF 82/182 reads (45%) | catalogued as rs746999253; called by mutect2, varscan2
- PLCL1 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 97/218 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs1229895654, COSV70820911; called by muse, mutect2, varscan2
- PLEC | c.11959T>C p.S3987P (on ENST00000322810 / NM_201380.4; = p.S3877P on NM_000445.5) | Missense Mutation (SNP) | VAF 283/401 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.4); catalogued as rs782148306; called by muse, mutect2, varscan2
- PLEC | c.1715C>T p.A572V (on ENST00000322810 / NM_201380.4; = p.A462V on NM_000445.5) | Missense Mutation (SNP) | VAF 218/771 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs782509734, COSV59701095; called by muse, mutect2, varscan2
- PLSCR1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 173/355 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769076735, COSV100678280; called by muse, mutect2, varscan2
- PLXNA2 | c.4042G>A p.V1348M | Missense Mutation (SNP) | VAF 119/249 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.69); catalogued as rs764579780, COSV65443814; called by muse, mutect2, varscan2
- PML | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 304/673 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs778503914; called by muse, mutect2, varscan2
- PML | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 168/330 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as rs371956504; called by muse, varscan2
- POGZ | c.3568A>G p.I1190V | Missense Mutation (SNP) | VAF 181/373 reads (49%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.833); catalogued as rs1225831017, COSV99305062; called by muse, mutect2, varscan2
- POLE | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 123/296 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1060500835, COSV57675385, COSV57683760; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLH | c.54dup p.V19Cfs*14 | Frame Shift Ins (INS) | VAF 165/341 reads (48%) | catalogued as rs1308019449; called by mutect2, varscan2
- PON2 | c.195del p.F65Lfs*5 | Frame Shift Del (DEL) | VAF 112/284 reads (39%) | catalogued as rs1201102139; called by mutect2, pindel, varscan2
- POPDC3 | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 111/247 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs1366658119; called by muse, mutect2, varscan2
- POTEG | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 99/450 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs767401356; called by muse, mutect2, varscan2
- POU2AF1 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 203/409 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67577201; called by muse, mutect2, varscan2
- POU2F3 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 139/357 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.551); catalogued as rs901357838, COSV52797109; called by muse, mutect2, varscan2
- POU3F2 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 350/688 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as COSV100099101; called by muse, mutect2, varscan2
- PPFIA4 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 155/335 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs561537732, COSV99829480; called by muse, mutect2, varscan2
- PPP1R14A | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 131/310 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs576186615, COSV100007296; called by muse, mutect2, varscan2
- PPP1R21 | c.2090G>A p.R697Q (on ENST00000294952 / NM_001135629.3; = p.R686Q on NM_152994.5) | Missense Mutation (SNP) | VAF 131/252 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs779018854; called by muse, mutect2, varscan2
- PPP1R3A | c.2867C>A p.S956* | Nonsense Mutation (SNP) | VAF 129/336 reads (38%) | catalogued as COSV52875102; called by muse, mutect2, varscan2
- PPP1R3A | c.1407del p.K469Nfs*11 | Frame Shift Del (DEL) | VAF 105/215 reads (49%) | catalogued as COSV52885548; called by mutect2, pindel, varscan2
- PPP2R3B | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 388/797 reads (49%) | catalogued as rs762666589, COSV101180743, COSV66812807; called by muse, mutect2, varscan2
- PPP4R3C | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 92/93 reads (99%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs901091510; called by muse, mutect2, varscan2
- PRAMEF6 | c.329A>G p.E110G | Missense Mutation (SNP) | VAF 114/516 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs764925438; called by muse, varscan2
- PRDM9 | c.1976C>T p.T659I | Missense Mutation (SNP) | VAF 230/574 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs199576336, COSV57005148; called by muse, mutect2, varscan2
- PRF1 | c.218G>C p.C73S | Missense Mutation (SNP) | VAF 262/505 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759913385; called by muse, mutect2, varscan2
- PRODH2 | c.529C>T p.R177W (on ENST00000301175; = p.R101W on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 251/492 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs770502391, COSV56558158; called by muse, mutect2, varscan2
- PROM2 | c.2299C>T p.R767C | Missense Mutation (SNP) | VAF 154/327 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs200518776, COSV58300773; called by muse, mutect2, varscan2
- PROSER2 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 127/241 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs753912940; called by muse, mutect2, varscan2
- PRR14L | c.5826G>A p.T1942= | Splice Region (SNP) | VAF 97/218 reads (44%) | catalogued as rs566717017; called by muse, mutect2, varscan2
- PRR14L | c.4682C>T p.A1561V | Missense Mutation (SNP) | VAF 111/263 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as rs756745478, COSV100392325; called by muse, varscan2
- PRR35 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 242/485 reads (50%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs530897636; called by muse, mutect2, varscan2
- PRSS8 | c.124del p.Q42Kfs*64 | Frame Shift Del (DEL) | VAF 142/358 reads (40%) | catalogued as COSV99571515; called by mutect2, pindel, varscan2
- PSG9 | c.1048C>A p.L350I | Missense Mutation (SNP) | VAF 109/248 reads (44%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.949); catalogued as COSV99392170; called by muse, mutect2, varscan2
- PSMD1 | c.1946G>A p.R649H | Missense Mutation (SNP) | VAF 141/273 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1441372370; called by muse, mutect2, varscan2
2,241 further variants in this file (1,440 protein-altering or splice-affecting, 683 silent, 118 other) are not listed here.
